Somatic mutation profile of tumor specimen TCGA-DD-AACV-01A (aliquot TCGA-DD-AACV-01A-11D-A40R-10) from TCGA case TCGA-DD-AACV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.8 years (19,660 days).
Specimen TCGA-DD-AACV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b12b2864-8f35-4981-af64-7bf57eba373d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACV-10A (Blood Derived Normal), aliquot TCGA-DD-AACV-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/449a1da1-8c69-42e5-9d50-0779e902756c

The open-access MAF lists 109 somatic variants for this specimen: 89 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 19, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKL5 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 94/98 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs797044858, CM1515030, COSV101184346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 68/75 reads (91%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV99491481; called by muse, mutect2, varscan2
- ACSM5 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100088988, COSV59373519; called by muse, varscan2
- ADAM7 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99444060; called by muse, mutect2, varscan2
- ADAT2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52793311; called by muse, mutect2, varscan2
- ADCY8 | c.2001T>G p.I667M | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99652533; called by muse, mutect2, varscan2
- ADGRA1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 55/59 reads (93%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV101192702; called by muse, mutect2, varscan2
- AGTR1 | c.333C>G p.N111K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100837062; called by muse, mutect2, varscan2
- AL592490.1 | c.2594T>C p.I865T | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs375289034; called by muse, mutect2, varscan2
- ANAPC2 | c.1186A>T p.I396F | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100119095; called by muse, mutect2
- AP002512.3 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 104/118 reads (88%) | catalogued as COSV99687979; called by muse, mutect2, varscan2
- ATF4 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV57478786; called by muse, mutect2, varscan2
- ATG2B | c.4235T>C p.L1412P | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99952083; called by muse, mutect2, varscan2
- ATP2C1 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV60760583; called by muse, mutect2, varscan2
- BPIFA3 | c.685+1G>C p.X229_splice | Splice Site (SNP) | VAF 35/130 reads (27%) | catalogued as COSV100967063; called by muse, mutect2, varscan2
- CACNA1B | c.6167G>A p.C2056Y | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (1); PolyPhen probably damaging (0.959); catalogued as COSV99497821; called by muse, mutect2, varscan2
- CAPN15 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99562486; called by muse, mutect2, varscan2
- CD200R1 | c.626A>T p.H209L (on ENST00000471858 / NM_170780.3; = p.H232L on NM_138806.4) | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV99867318; called by muse, mutect2, varscan2
- CDH9 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 50/226 reads (22%) | catalogued as COSV99141309, COSV99145337; called by muse, mutect2
- CP | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99224149; called by muse, mutect2, varscan2
- CRMP1 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100271910; called by muse, mutect2, varscan2
- CTF1 | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99688299; called by muse, mutect2, varscan2
- CTIF | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 55/60 reads (92%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV99837663; called by muse, mutect2, varscan2
- DCAF1 | c.121T>A p.L41M | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100244473; called by muse, mutect2, varscan2
- DGKB | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99340002; called by muse, mutect2, varscan2
- DIP2B | c.1516A>C p.I506L | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV99998601; called by muse, mutect2, varscan2
- DNAJA4 | c.542G>T p.C181F (on ENST00000343789; = p.C210F on NM_018602.3) | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV100655190; called by muse, mutect2, varscan2
- GALNT17 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758121306, COSV100353306, COSV61160204; called by muse, mutect2, varscan2
- GPR1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV101329852; called by muse, mutect2, varscan2
- GRIN3A | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100701540; called by muse, mutect2, varscan2
- GYS2 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs141614479; called by muse, mutect2, varscan2
- HSP90AA1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as rs778338593, COSV99355332; called by muse, mutect2, varscan2
- IL6R | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV100690856; called by muse, mutect2, varscan2
- INS | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.9); PolyPhen benign (0.193); catalogued as COSV99171147; called by muse, mutect2, varscan2
- IRF2BPL | c.1031T>C p.L344S | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99468155; called by muse, mutect2, varscan2
- KIF18A | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs1234109074, COSV54184921; called by muse, mutect2
- KMT2E | c.3590A>C p.D1197A | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV99996397; called by muse, mutect2, varscan2
- KMT2E | c.4037A>G p.N1346S | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99996399; called by muse, mutect2, varscan2
- L1CAM | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as rs1387424271, COSV100649187; called by muse, mutect2, varscan2
- LAMA5 | c.3326A>G p.Y1109C | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1007032446, COSV99440304; called by muse, mutect2, varscan2
- LRRK2 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.125); catalogued as rs1427858582, COSV100110323; called by muse, mutect2, varscan2
- LRRK2 | c.3667A>T p.R1223W | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100110324; called by muse, mutect2, varscan2
- MIA3 | c.502A>T p.N168Y | Missense Mutation (SNP) | VAF 163/340 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100719459; called by muse, mutect2, varscan2
- MIPEP | c.1543+2T>A p.X515_splice | Splice Site (SNP) | VAF 66/132 reads (50%) | catalogued as COSV101193131; called by muse, mutect2, varscan2
- MORC1 | c.2390G>A p.S797N | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99226312; called by muse, mutect2, varscan2
- MSGN1 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99808759; called by muse, mutect2, varscan2
- MYCBP2 | c.10747G>A p.E3583K (on ENST00000357337; = p.E3621K on NM_015057.5) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV62035970; called by muse, mutect2, varscan2
- MYH1 | c.2539G>T p.A847S | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV99876075; called by muse, mutect2, varscan2
- NFYC | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.075); catalogued as COSV100438498; called by muse, mutect2, varscan2
- NTNG1 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV99637716; called by muse, mutect2, varscan2
- OR10Z1 | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs768348063, COSV100779026; called by muse, mutect2, varscan2
- OR2J3 | c.166T>G p.S56A | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV101013636; called by muse, mutect2, varscan2
- OTOGL | c.3647G>T p.G1216V (on ENST00000547103; = p.G1207V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV101509312; called by muse, mutect2, varscan2
- PCLO | c.5914A>G p.S1972G | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1347294200, COSV100433282; called by muse, mutect2, varscan2
- PREX1 | c.2108C>G p.A703G | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100906381; called by muse, mutect2, varscan2
- PRKAG2 | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.161); catalogued as COSV99835400; called by muse, mutect2, varscan2
- PYGO1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100114662; called by muse, mutect2, varscan2
- RETREG2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.035); catalogued as rs1194375778, COSV99811555; called by muse, mutect2, varscan2
- RGS4 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100905577; called by muse, mutect2, varscan2
- SHROOM2 | c.2670G>T p.R890S | Missense Mutation (SNP) | VAF 121/132 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101098701; called by muse, mutect2, varscan2
- SIM2 | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs962246418, COSV51772928; called by muse, mutect2, varscan2
- SLC12A4 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100311801; called by muse, mutect2, varscan2
- SLC25A6 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV100452294; called by muse, mutect2
- SLC9A1 | c.1139A>G p.K380R | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as rs1197316075, COSV99849733; called by muse, mutect2, varscan2
- SMG8 | c.2360G>A p.G787D | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1412524110, COSV99958857; called by muse, mutect2, varscan2
- SPATA5L1 | c.1724C>G p.A575G | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99973102; called by muse, mutect2, varscan2
- STAG1 | c.3548G>C p.R1183T | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.2); catalogued as COSV99365661; called by muse, mutect2, varscan2
- STXBP5 | c.3091G>A p.G1031S (on ENST00000321680 / NM_001127715.2; = p.G995S on NM_139244.4) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as rs757798078, COSV51649312, COSV99470382; called by muse, mutect2, varscan2
- STYXL2 | c.63C>A p.N21K | Missense Mutation (SNP) | VAF 160/337 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs372564326, COSV54805582; called by muse, mutect2, varscan2
- TFEB | c.962T>C p.M321T | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100026230; called by muse, mutect2, varscan2
- TIMELESS | c.3405G>T p.R1135S | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.089); catalogued as COSV99974025; called by muse, mutect2, varscan2
- TMEM94 | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100050508; called by muse, mutect2, varscan2
- TTI2 | c.1207A>G p.R403G | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100659733; called by muse, mutect2, varscan2
- VPS13D | c.6610C>T p.P2204S | Missense Mutation (SNP) | VAF 96/193 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); catalogued as rs753375836, COSV99166860; called by muse, mutect2, varscan2
- WDR92 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as COSV99718325; called by muse, mutect2, varscan2
- WWOX | c.593A>T p.K198M | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs577414279, COSV101283064; called by muse, mutect2, varscan2
- ZBTB38 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1478249888, COSV100375671; called by muse, mutect2, varscan2
- ZIC2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 159/274 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV100891781; called by muse, mutect2, varscan2
- ZNF569 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 76/79 reads (96%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100386494; called by muse, mutect2, varscan2
- ZNF780A | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 471/581 reads (81%) | catalogued as rs368327296; called by muse, mutect2, varscan2
- ZNF91 | c.1855A>G p.R619G | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.758); catalogued as COSV100322803; called by muse, mutect2, varscan2
- HMGCS1 | c.229del p.M77Wfs*28 | Frame Shift Del (DEL) | VAF 195/342 reads (57%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.53); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MRM1 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- MUC2 | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- OR5H2 | c.184_215del p.I62Lfs*3 | Frame Shift Del (DEL) | VAF 49/158 reads (31%) | called by mutect2, pindel, varscan2
- TMEM39A | c.323_325del p.S108del | In Frame Del (DEL) | VAF 50/132 reads (38%) | called by pindel, varscan2
- VWA8 | c.1935dup p.Q646Tfs*29 | Frame Shift Ins (INS) | VAF 63/159 reads (40%) | called by mutect2, pindel, varscan2
- AMER2 | c.1500C>A p.P500= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV100766274, COSV100766361; called by muse, mutect2, varscan2
- C5 | c.4884A>G p.K1628= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as rs1290117730, COSV56333973; called by muse, mutect2, varscan2
- CADPS | c.3144G>A p.P1048= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as rs368961255, COSV51903526; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAPN15 | c.555G>A p.P185= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs773340995, COSV99562484; called by muse, mutect2, varscan2
- CHRNA7 | c.960C>T p.H320= | Silent (SNP) | VAF 237/493 reads (48%) | catalogued as rs753933393, COSV60968830; called by muse, mutect2, varscan2
- DCLRE1A | c.294A>G p.P98= | Silent (SNP) | VAF 65/70 reads (93%) | catalogued as COSV100800379; called by muse, mutect2, varscan2
- EXOSC4 | c.6G>A p.A2= | Silent (SNP) | VAF 110/213 reads (52%) | catalogued as rs1364994354, COSV100284085; called by muse, varscan2
- IGSF10 | c.567C>T p.F189= | Silent (SNP) | VAF 86/214 reads (40%) | catalogued as rs754580450, COSV99180469; called by muse, mutect2, varscan2
- MSI2 | c.900T>C p.S300= | Silent (SNP) | VAF 100/271 reads (37%) | catalogued as rs376818853; called by muse, mutect2, varscan2
- PDLIM5 | c.1050G>A p.K350= | Silent (SNP) | VAF 102/109 reads (94%) | catalogued as COSV100523776; called by muse, mutect2, varscan2
- SERPINB2 | c.252G>A p.Q84= | Silent (SNP) | VAF 67/73 reads (92%) | catalogued as COSV100208462; called by muse, mutect2, varscan2
- SIRPB1 | c.813C>T p.T271= | Silent (SNP) | VAF 77/245 reads (31%) | catalogued as COSV99498410; called by muse, mutect2, varscan2
- SLC39A12 | c.114G>C p.G38= | Silent (SNP) | VAF 95/193 reads (49%) | catalogued as COSV101070067; called by muse, mutect2, varscan2
- SPEG | c.2607C>A p.P869= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs969309838, COSV100404627, COSV56664625; called by muse, mutect2, varscan2
- STXBP5L | c.2082T>A p.S694= | Silent (SNP) | VAF 72/144 reads (50%) | catalogued as COSV99874500; called by muse, mutect2, varscan2
- TARS2 | c.1482G>A p.L494= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV100945995; called by muse, mutect2, varscan2
- TLR8 | c.1593T>C p.H531= (on ENST00000218032 / NM_138636.5; = p.H549= on NM_016610.4) | Silent (SNP) | VAF 19/200 reads (10%) | catalogued as COSV99487049; called by muse, mutect2
- UNC79 | c.1281C>T p.T427= (on ENST00000393151 / NM_001346218.2; = p.T250= on NM_020818.5) | Silent (SNP) | VAF 72/147 reads (49%) | catalogued as COSV99828100; called by muse, mutect2, varscan2
- VIRMA | c.2448T>C p.F816= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs1308508461, COSV99888503; called by muse, mutect2, varscan2
- PRDM15 | c.-866C>T | 5'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs755068109, COSV99520163; called by muse, varscan2
